Somatic mutation profile of tumor specimen TCGA-MP-A4SW-01A (aliquot TCGA-MP-A4SW-01A-21D-A24P-08) from TCGA case TCGA-MP-A4SW, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.8 years (19,640 days).
Specimen TCGA-MP-A4SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87fcadb6-f93b-4665-8737-99653ba137ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4SW-10A (Blood Derived Normal), aliquot TCGA-MP-A4SW-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04cf76d7-4dc2-440d-a151-ce3a2d20fa5b

The open-access MAF lists 69 somatic variants for this specimen: 47 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Nonsense Mutation 4, Splice Site 2, Splice Region 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 152/267 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 36/103 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRIM2 | c.716C>A p.S239* (on ENST00000437508; = p.S266* on NM_015271.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs746386202, COSV100107940; ClinVar: pathogenic; called by muse, mutect2
- ADGRE2 | c.1931A>T p.K644M | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100216033; called by muse, mutect2
- AMIGO1 | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100881063; called by muse, mutect2, varscan2
- ATG16L1 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.517); catalogued as COSV100731317; called by muse, mutect2, varscan2
- CACNA1E | c.5101G>A p.V1701M | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs762078001, COSV62389873; called by muse, mutect2, varscan2
- CALML3 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs1011051689, COSV100178810; called by muse, mutect2, varscan2
- CAMTA1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100349518; called by muse, mutect2
- CCDC116 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV53042653; called by muse, mutect2, varscan2
- COL7A1 | c.7878T>A p.G2626= | Splice Region (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99866272; called by muse, mutect2, varscan2
- DGKH | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV99818818; called by muse, mutect2, varscan2
- DMBT1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 55/535 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV57547797; called by muse, mutect2, varscan2
- EIF4B | c.981T>C p.G327= | Splice Region (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100016801; called by muse, mutect2, varscan2
- GRIA2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1408962625, COSV52409063; called by muse, mutect2, varscan2
- GRIN2B | c.3689C>T p.T1230M | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1263518250, COSV101663035; called by muse, mutect2
- GUF1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99877298; called by muse, mutect2, varscan2
- H4C12 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs779137595, COSV100694723; called by muse, mutect2, varscan2
- IGFBP3 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99298346; called by muse, mutect2, varscan2
- MADD | c.2839G>T p.E947* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100211457; called by muse, mutect2, varscan2
- MAFG | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100155707; called by muse, mutect2
- MAP2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV99559952; called by muse, mutect2
- MBNL3 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100898473; called by muse, mutect2
- MPP6 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs746154850, COSV99757501; called by muse, mutect2, varscan2
- NEUROG2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as rs1384268695, COSV100511844, COSV99046275; called by muse, mutect2
- NSD2 | c.2375A>G p.Y792C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100373300; called by muse, mutect2, varscan2
- PADI4 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752032759, COSV64923993; called by muse, mutect2
- PAPPA2 | c.3227T>C p.F1076S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100868138, COSV62807265; called by muse, mutect2
- PCDHB15 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.939); catalogued as rs1371705552, COSV50960913; called by muse, mutect2, varscan2
- PCLO | c.13346G>C p.R4449T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100432696; called by muse, mutect2, varscan2
- PLXNB2 | c.2988-1G>T p.X996_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100834059; called by muse, mutect2, varscan2
- PTCHD1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV101037659; called by muse, mutect2
- PTPRN2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs567734269, COSV66104639; called by muse, mutect2, varscan2
- RAD52 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV99942572; called by muse, mutect2, varscan2
- RASAL2 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100862495; called by muse, mutect2
- RBM10 | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV61308721; called by muse, mutect2, varscan2
- ROCK2 | c.3709G>C p.E1237Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100255015; called by muse, mutect2, varscan2
- SOX6 | c.1598G>T p.G533V (on ENST00000528429 / NM_001145819.2; = p.G506V on NM_017508.3) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as rs765364888, COSV100322204; called by muse, mutect2, varscan2
- TP53BP2 | c.415G>C p.E139Q (on ENST00000343537 / NM_001031685.3; = p.E10Q on NM_005426.2) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100636634; called by muse, mutect2, varscan2
- TRIM72 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs769578887, COSV57250671; called by muse, mutect2
- ZNF341 | c.1649C>T p.S550F (on ENST00000375200 / NM_001282935.1; = p.S543F on NM_032819.4) | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100677861; called by muse, mutect2
- ZNF479 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100482748; called by muse, mutect2, varscan2
- ZNF587 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.515); catalogued as COSV100299488; called by muse, mutect2, varscan2
- CCDC74A | c.1006_1007+4del p.X336_splice | Splice Site (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- IZUMO2 | c.426del p.E143Kfs*86 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by pindel, varscan2*
- TPTE | c.272C>A p.S91Y (on ENST00000618007 / NM_199261.4; = p.S73Y on NM_199259.4) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF804A | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- AC242842.3 | c.231C>T p.F77= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.699C>T p.P233= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs540897686, COSV51097285; called by muse, mutect2, varscan2
- CSPP1 | c.2706C>T p.L902= (on ENST00000676605; = p.L861= on NM_024790.6) | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV99138558; called by muse, mutect2
- DPPA4 | c.535C>T p.L179= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100169427; called by muse, mutect2, varscan2
- ESRRB | c.360C>T p.C120= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV55066298; called by muse, mutect2, varscan2
- GPN2 | c.162C>T p.Y54= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs774416861, COSV100658794; called by muse, mutect2, varscan2
- HSPG2 | c.7377C>T p.L2459= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs148384253, COSV65972995; called by muse, mutect2, varscan2
- IGHG1 | c.438G>C p.V146= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- KRT84 | c.948G>A p.T316= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as rs555015096, COSV57770838; called by muse, mutect2, varscan2
- MCL1 | c.999G>T p.L333= | Silent (SNP) | VAF 33/282 reads (12%) | catalogued as COSV100329563; called by muse, mutect2, varscan2
- MROH7 | c.2484C>T p.V828= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100273474; called by muse, mutect2
- MUC16 | c.19779A>T p.A6593= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV101199950; called by muse, mutect2, varscan2
- MYO18B | c.6489G>C p.G2163= | Silent (SNP) | VAF 50/257 reads (19%) | catalogued as COSV100123670; called by muse, mutect2, varscan2
- PRKAA1 | c.438G>T p.V146= | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as COSV99713257; called by muse, mutect2, varscan2
- PXN | c.1632C>T p.G544= (on ENST00000228307 / NM_001080855.3; = p.G510= on NM_002859.4) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99935894; called by muse, mutect2, varscan2
- SH3BP2 | c.867C>T p.P289= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs151102529, COSV62555669; called by muse, mutect2
- SMTNL2 | c.1161C>T p.C387= (on ENST00000389313 / NM_001114974.2; = p.C243= on NM_198501.3) | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs534678064, COSV100130704; called by muse, mutect2, varscan2
- TACR3 | c.198G>A p.A66= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV59197730; called by muse, mutect2
- VWF | c.6561C>T p.N2187= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs151250563; called by muse, mutect2, varscan2
- ZNF432 | c.1902C>T p.F634= | Silent (SNP) | VAF 19/211 reads (9%) | catalogued as COSV99659249; called by muse, mutect2
- ZNF668 | c.1293G>T p.G431= | Silent (SNP) | VAF 37/220 reads (17%) | catalogued as COSV100336667; called by muse, mutect2, varscan2
- DENND1A | c.1577+855G>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
